Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RG, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RG-01A (Primary Tumor).

[page 1 of 2]
ICD O-3

Oligoastrocytoma, grade II
9382/3

Site ^{C60E} Brain, supratentorial NOS
C71.0

^{Path} Brain, temporal lobe
J1014113 C71.2

Nature of material: Brain
Received on:

Macroscopy:

Received four bottles containing:

Bottle 1- FREEZER CONTROL: Structure of rounded, whitish and soft tissue, measuring 0.5 x 0.5 x 0.2 cm.

Bottle 2 - Four fragments of irregular, whitish and soft tissue, measuring together 1.0 x 0.3 x 0.2 m.

Bottle 3 - A piece of whitish and soft tissue, measuring 0.5 x 0.4 x 0.2 cm.

Bottle 4 - Two brown structures of soft and rounded tissue, the largest measuring 3.2 x 2.0 x 1.2 cm and the smallest 1.5 x 1.0 x 0.5 cm.

Microscopy:

Histological sections stained with hematoxylin and eosin showed fragments of neocortex with diffuse infiltration by low-grade glial neoplasm, mainly located in the white matter, which consists of distinct phenotype cells, which present interspersed among themselves.

The predominant cell pattern is represented by rounded cell nuclei with delicate and granular chromatin, with inconspicuous nucleoli. The cytoplasm is scarce, with imprecise limits. It can be observed in some areas, the presence of perinuclear halos. These cells infiltrate the adjacent cortex, committing up to layer I, with frequent neuronal satellitosis.

The other cell component, with lesser quantity of cells is represented by irregular and sometimes elongated nuclei, with dense chromatin and eosinophilic cytoplasm with imprecise limits.

The tumor shows areas with increased cellularity, in which the neuropil displays rarefaction and eventual microcysts. Mitotic figures are rare. It was not observed vessels with microvascular proliferation and / or necrotic foci.

PER-OPERATIVE

Smears show, in sent fragments, diffuse low-grade glial neoplasm, consisting of elongated nuclei cells with mild dyskaryosis in a rich fibrillar plot. It is note also some round nuclei cells. There are some eosinophilic and amorphous structures, suggesting Rosenthal fibers, but not conclusive.

Conclusion: Low-grade glioma, in this material.

Diagnosis:

Resection product of brain lesion in the left temporal region:

- Oligoastrocytoma, grade II WHO (ICD-O 9382/3).

NOTE:

- The oligodendroglial component is predominant in this material.

Award of 1p/19q deletion analysis:

[page 2 of 2]
The hybridizations were performed on 5 micrometers thick sections of formalin-fixed and paraffin-embedded neoplastic tissue (FFPE) in the most representative tumor area with 1p36/1q25 and 19q13/19p13 probe. 100 to 200 were evaluated in each slide cores.

In this case: The ratio of signals from 1p/1q probes was 0,58. The ratio of signals from 19q/19p probes was 0,62. Conclusion: Diffuse oligoastrocitoma grade II WHO with co-deletion of 1p/19q.

PROFESSIONAL PARTICIPANTS OF REPORT

HI/AA Discrepancy		✓

Source: NCI Genomic Data Commons file 158a0ac5-e5ca-470b-abb1-d82a6bcff9e8 (TCGA-TQ-A7RG.396F6EAB-2B8F-4054-AACA-31BC916FB9D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).